Somatic mutation profile of tumor specimen TCGA-25-1319-01A (aliquot TCGA-25-1319-01A-01W-0492-08) from TCGA case TCGA-25-1319, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,786 days).
Specimen TCGA-25-1319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7188402-f402-4346-9e29-45b01b25ec6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1319-10A (Blood Derived Normal), aliquot TCGA-25-1319-10A-01D-0452-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba0816a1-2fe1-42c3-baca-230d6164abb2

The open-access MAF lists 101 somatic variants for this specimen: 86 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Frame Shift Ins 24, Silent 13, Nonsense Mutation 4, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- AP1S1 | c.364dup p.D122Gfs*18 | Frame Shift Ins (INS) | VAF 26/139 reads (19%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 58/370 reads (16%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 96/616 reads (16%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 52/418 reads (12%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 289/350 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55661582; called by muse, mutect2, varscan2
- ARHGAP21 | c.4849G>A p.D1617N | Missense Mutation (SNP) | VAF 105/493 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV57604106; called by muse, mutect2, varscan2
- ARID2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV57600386; called by muse, mutect2, varscan2
- ARMCX1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 117/312 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV65705008; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 83/514 reads (16%) | catalogued as rs745882580; called by mutect2, varscan2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 20/164 reads (12%) | catalogued as rs754078059; called by mutect2, varscan2
- CALCR | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 280/1037 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs544410123, COSV64006936; called by muse, mutect2, varscan2
- CDH17 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as COSV50326778; called by muse, mutect2, varscan2
- CHMP4B | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 257/593 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54136211, COSV99459866; called by muse, mutect2, varscan2
- CORO1B | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58168670; called by muse, mutect2, varscan2
- DEPDC1B | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV54008970, COSV54009271; called by muse, mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | catalogued as rs760008381; called by mutect2, varscan2
- DNAJC11 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 153/333 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99602306; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 47/376 reads (13%) | catalogued as rs752538869; called by mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 32/135 reads (24%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAL | c.700G>A p.V234I (on ENST00000269162 / NM_001142339.3; = p.V311I on NM_182978.4) | Missense Mutation (SNP) | VAF 377/897 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM165376, COSV52333987; called by muse, mutect2, varscan2
- GPR139 | c.276G>C p.L92F | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV100429790, COSV58505306; called by muse, mutect2
- GRK3 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767010348, COSV60793388; called by muse, mutect2, varscan2
- HK3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV52838340; called by muse, mutect2, varscan2
- HTRA2 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 130/1520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51206693; called by muse, mutect2
- INHBA | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 194/699 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749989847, COSV54220498; called by muse, mutect2, varscan2
- INSYN2A | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779113272, COSV54734671; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 57/355 reads (16%) | catalogued as rs761558950; called by mutect2, varscan2
- KCNH7 | c.1409T>G p.F470C | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59791986; called by muse, mutect2, varscan2
- L2HGDH | c.808A>G p.S270G | Missense Mutation (SNP) | VAF 277/527 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV55556723; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 73/502 reads (15%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 52/300 reads (17%) | catalogued as rs757410385; called by mutect2, varscan2
- LYST | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV67705375; called by muse, mutect2, varscan2
- MAGEB4 | c.787A>C p.S263R | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66775524; called by muse, mutect2, varscan2
- MALT1 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs564979419, COSV61935200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 108/502 reads (22%) | catalogued as rs777328830; called by mutect2, varscan2
- MRPL13 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100085501; called by muse, mutect2, varscan2
- MRPL13 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100085504; called by muse, mutect2, varscan2
- NDUFB9 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 168/1924 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV52674605; called by muse, mutect2
- NEXN | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 89/347 reads (26%) | catalogued as COSV53942443; called by muse, mutect2, varscan2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 44/332 reads (13%) | catalogued as rs763440516; called by mutect2, varscan2
- NTHL1 | c.374dup p.V127Gfs*43 (on ENST00000219066; = p.V119Gfs*43 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | catalogued as rs763525759; called by mutect2, varscan2
- OR10H2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 184/707 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs549916970, COSV59946004; called by muse, mutect2, varscan2
- OR10K1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 103/602 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148047665; called by muse, mutect2, varscan2
- OR2A12 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68821194; called by muse, mutect2, varscan2
- OSBPL2 | c.298C>T p.P100S (on ENST00000313733 / NM_144498.4; = p.P88S on NM_014835.4) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58215983; called by muse, mutect2, varscan2
- PCDH10 | c.2213T>G p.V738G | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV52090601; called by muse, mutect2, varscan2
- PCDHGB6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53921168; called by muse, mutect2, varscan2
- PCNX1 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs373015087, COSV53095227; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 20/194 reads (10%) | catalogued as rs746342377; called by mutect2, varscan2
- PLXNA3 | c.5168G>A p.R1723H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63753606; called by muse, varscan2
- PRDM9 | c.2480C>G p.T827R | Missense Mutation (SNP) | VAF 373/2691 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57004441; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 47/358 reads (13%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PTCHD3 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1351637148, COSV71256494; called by muse, varscan2
- RAPH1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as COSV55582731; called by muse, mutect2, varscan2
- RBMXL1 | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV53099714; called by muse, mutect2, varscan2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 28/161 reads (17%) | catalogued as rs762949421; called by mutect2, varscan2
- RYR1 | c.10916C>T p.T3639M | Missense Mutation (SNP) | VAF 130/1357 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs369390137; called by muse, mutect2
- SCN9A | c.4061C>A p.T1354K (on ENST00000303354; = p.T1343K on NM_002977.3) | Missense Mutation (SNP) | VAF 108/428 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV57605071; called by muse, varscan2
- SETD5 | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56709173; called by muse, mutect2, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SNRK | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.271); catalogued as COSV56067076; called by muse, mutect2, varscan2
- SPIN4 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as COSV58737859; called by muse, mutect2, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 30/248 reads (12%) | catalogued as rs748467821; called by mutect2, varscan2
- SRSF1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 101/110 reads (92%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV51964546; called by muse, mutect2, varscan2
- STAT6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.411); catalogued as rs780257871, COSV55670051; called by muse, mutect2, varscan2
- TAGLN3 | c.141dup p.G48Rfs*21 | Frame Shift Ins (INS) | VAF 22/248 reads (9%) | catalogued as rs762583525; called by mutect2, pindel
- TDRD9 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs377183290, COSV59144770; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 101/710 reads (14%) | catalogued as rs782753958; called by mutect2, varscan2
- TMC2 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 226/1019 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs778718713, COSV62651135; called by muse, mutect2, varscan2
- TMEM69 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV63432287; called by muse, mutect2, varscan2
- TNFSF13 | c.109dup p.A37Gfs*88 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | catalogued as rs775253472; called by pindel, varscan2
- TPCN1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010154228, COSV59233922; called by muse, mutect2, varscan2
- TRIM62 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 13/391 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs918477501, COSV52221142; called by muse, mutect2
- TRPM7 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57915115; called by muse, mutect2, varscan2
- TTLL4 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 135/542 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV51435659; called by muse, mutect2, varscan2
- YTHDC1 | c.1723C>T p.R575* (on ENST00000344157 / NM_001031732.4; = p.R557* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 53/161 reads (33%) | catalogued as COSV60009563; called by muse, mutect2, varscan2
- ZIC1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 110/560 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99292041; called by muse, mutect2, varscan2
- ZSWIM8 | c.5085dup p.Y1696Lfs*3 (on ENST00000605216 / NM_001242487.2; = p.Y1701Lfs*3 on NM_015037.3) | Frame Shift Ins (INS) | VAF 47/232 reads (20%) | catalogued as rs769663113; called by mutect2, varscan2
- FBXO16 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 49/773 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- IGHV3-38 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- OR51B6 | c.266A>T p.E89V | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- P2RY4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.444); called by muse, mutect2
- PPT2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 110/1218 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.052); called by muse, mutect2
- SRCAP | c.8711C>T p.A2904V | Missense Mutation (SNP) | VAF 38/536 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS19 | c.2787C>T p.S929= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV50738210; called by muse, mutect2, varscan2
- BICRAL | c.1939C>T p.L647= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as COSV58404484; called by muse, mutect2, varscan2
- CAPN10 | c.1230G>A p.A410= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs758982958, COSV54375573; called by muse, mutect2, varscan2
- FLG | c.10203G>T p.G3401= | Silent (SNP) | VAF 216/1011 reads (21%) | catalogued as COSV64245638; called by muse, mutect2, varscan2
- FOXD4L4 | c.558C>T p.P186= | Silent (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- KATNIP | c.1470G>A p.S490= | Silent (SNP) | VAF 321/1116 reads (29%) | catalogued as rs375213710, COSV55176860; ClinVar: likely benign; called by muse, mutect2, varscan2
- NSF | c.1080C>T p.G360= | Silent (SNP) | VAF 124/542 reads (23%) | catalogued as rs745925224, COSV99833885; called by muse, mutect2, varscan2
- RELN | c.6963G>A p.T2321= | Silent (SNP) | VAF 61/288 reads (21%) | catalogued as rs577520481, COSV58993873; called by muse, mutect2, varscan2
- SDK1 | c.2148G>T p.V716= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as rs1470036071, COSV67358089; called by muse, mutect2, varscan2
- SPDL1 | c.1113T>G p.L371= | Silent (SNP) | VAF 109/321 reads (34%) | catalogued as rs772753899, COSV54667568; called by muse, mutect2, varscan2
- TIPARP | c.1434C>T p.Y478= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV55813603; called by muse, mutect2, varscan2
- TRERF1 | c.1863G>A p.S621= | Silent (SNP) | VAF 152/332 reads (46%) | catalogued as rs148325036; called by muse, varscan2
- ZFHX4 | c.7392G>A p.S2464= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs761611371, COSV50650716, COSV50683357; called by muse, mutect2, varscan2
- AL162417.1 | c.397-17052C>G | Intron (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503701 ins G | 5'Flank (INS) | VAF 12/80 reads (15%) | catalogued as rs757261047; called by mutect2, varscan2
